Somatic mutation profile of tumor specimen TCGA-P4-A5E8-01A (aliquot TCGA-P4-A5E8-01A-11D-A28G-10) from TCGA case TCGA-P4-A5E8, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 57.9 years (21,132 days).
Specimen TCGA-P4-A5E8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 04a1c260-ea62-4931-8a1a-867ba7819744.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-P4-A5E8-11A (Solid Tissue Normal), aliquot TCGA-P4-A5E8-11A-12D-A28G-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/01e274bc-1bf9-40a2-9ec1-c9fa42929d4f

The open-access MAF lists 43 somatic variants for this specimen: 37 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 22, Frame Shift Del 8, Silent 6, In Frame Del 3, Nonsense Mutation 2, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC1 | c.2251G>A p.E751K | Missense Mutation (SNP) | VAF 50/234 reads (21%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.568); catalogued as COSV60685091; called by muse, mutect2, varscan2
- APC | c.1151G>T p.S384I | Missense Mutation (SNP) | VAF 61/150 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as CD021189, COSV57341711; called by muse, mutect2, varscan2
- ARSL | c.1063G>A p.G355S | Missense Mutation (SNP) | VAF 57/83 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM078456, COSV66965159; called by muse, mutect2, varscan2
- DCAF13 | c.130G>T p.A44S | Missense Mutation (SNP) | VAF 44/124 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52571645; called by muse, mutect2, varscan2
- EPB41L1 | c.1291C>G p.L431V | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.471); catalogued as COSV52437278, COSV99148835; called by muse, mutect2, varscan2
- EPB41L4A | c.1688C>T p.P563L | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); catalogued as COSV54868571; called by muse, mutect2, varscan2
- FAM83D | c.486G>A p.V162= | Splice Region (SNP) | VAF 50/140 reads (36%) | catalogued as COSV54157314; called by muse, mutect2, varscan2
- HOXA7 | c.514C>T p.R172C | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780389627, COSV54217456, COSV54219077; called by muse, mutect2, varscan2
- ITIH5 | c.1187G>A p.R396Q | Missense Mutation (SNP) | VAF 31/59 reads (53%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.918); catalogued as rs368004189; called by muse, mutect2, varscan2
- KIF13B | c.3112G>C p.V1038L | Missense Mutation (SNP) | VAF 9/129 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.272); catalogued as COSV72954367; called by muse, mutect2
- LYSMD1 | c.187C>A p.Q63K | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.103); catalogued as COSV64420064; called by muse, mutect2, varscan2
- MAST4 | c.3761C>A p.S1254Y (on ENST00000403625 / NM_001164664.2; = p.S1065Y on NM_015183.3) | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV55123644; called by muse, mutect2, varscan2
- MBD1 | c.758G>A p.R253H | Missense Mutation (SNP) | VAF 67/200 reads (34%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as rs759614155, COSV54001029, COSV99496790; called by muse, mutect2, varscan2
- NOX5 | c.1652C>A p.S551Y | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as COSV52988355; called by muse, mutect2, varscan2
- PLXNB2 | c.422A>T p.K141M | Missense Mutation (SNP) | VAF 33/98 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV63781375; called by muse, mutect2, varscan2
- PLXNB2 | c.421A>G p.K141E | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.867); catalogued as COSV63781380; called by muse, mutect2, varscan2
- POSTN | c.239G>T p.C80F | Missense Mutation (SNP) | VAF 54/106 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65712839; called by muse, varscan2
- POU2AF1 | c.434C>T p.P145L | Missense Mutation (SNP) | VAF 118/303 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.04); catalogued as rs1452228207, COSV101260695, COSV67577207; called by muse, mutect2, varscan2
- RAB40B | c.284A>T p.D95V | Missense Mutation (SNP) | VAF 46/115 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53915955; called by muse, mutect2, varscan2
- SPTBN4 | c.7291C>T p.L2431F | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.681); catalogued as COSV58948501; called by muse, mutect2, varscan2
- TMEM184C | c.162C>G p.I54M | Missense Mutation (SNP) | VAF 35/60 reads (58%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.471); catalogued as COSV56853539; called by muse, mutect2, varscan2
- TP53BP1 | c.2554C>T p.Q852* | Nonsense Mutation (SNP) | VAF 25/66 reads (38%) | catalogued as COSV55500438; called by muse, mutect2, varscan2
- TSGA10 | c.2048G>A p.R683Q | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as rs770482857, COSV100747760, COSV61823142; called by muse, mutect2, varscan2
- ZNF577 | c.1119G>T p.E373D | Missense Mutation (SNP) | VAF 37/78 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV56814696, COSV56816457, COSV56817427; called by muse, mutect2, varscan2
- DMXL1 | c.8204_8206del p.G2735del | In Frame Del (DEL) | VAF 76/265 reads (29%) | called by pindel, varscan2
- EIF4G3 | c.4741_4743del p.E1581del | In Frame Del (DEL) | VAF 32/86 reads (37%) | called by pindel, varscan2
- FAT1 | c.1771_1772del p.V591Ffs*4 | Frame Shift Del (DEL) | VAF 22/53 reads (42%) | called by mutect2, pindel, varscan2
- GPR37L1 | c.1070_1074del p.L357Qfs*79 | Frame Shift Del (DEL) | VAF 38/82 reads (46%) | called by mutect2, pindel, varscan2
- HIF1A | c.616_625delinsT p.N206_Q209delins* | Nonsense Mutation (DEL) | VAF 39/115 reads (34%) | called by pindel, varscan2*
- HOXD10 | c.39_41del p.F13del | In Frame Del (DEL) | VAF 27/70 reads (39%) | called by mutect2, pindel, varscan2
- IGFBP6 | c.348del p.P117Lfs*16 | Frame Shift Del (DEL) | VAF 25/71 reads (35%) | called by mutect2, pindel, varscan2
- KIAA1217 | c.4030_4031del p.D1344Ffs*15 | Frame Shift Del (DEL) | VAF 112/309 reads (36%) | called by mutect2, pindel, varscan2
- MSH4 | c.1782del p.X594_splice | Splice Site (DEL) | VAF 22/56 reads (39%) | called by mutect2, pindel*, varscan2
- NIPBL | c.2922_2925del p.K975Wfs*3 | Frame Shift Del (DEL) | VAF 17/73 reads (23%) | called by mutect2, pindel, varscan2
- SAMD9 | c.3916del p.I1306Yfs*5 | Frame Shift Del (DEL) | VAF 10/30 reads (33%) | called by mutect2, pindel, varscan2
- THUMPD2 | c.1188_1189del p.R396Sfs*13 | Frame Shift Del (DEL) | VAF 22/105 reads (21%) | called by pindel, varscan2
- TRIM39 | c.761_780+2del | Frame Shift Del (DEL) | VAF 14/38 reads (37%) | called by mutect2, varscan2
- CARMIL2 | c.1740C>T p.D580= | Silent (SNP) | VAF 19/47 reads (40%) | catalogued as COSV58025750; called by muse, mutect2, varscan2
- CCDC171 | c.2655C>T p.D885= | Silent (SNP) | VAF 14/40 reads (35%) | catalogued as rs779856240, COSV52636190; called by muse, mutect2, varscan2
- DNAI2 | c.1419G>T p.L473= | Silent (SNP) | VAF 28/82 reads (34%) | catalogued as COSV56758426; called by muse, mutect2, varscan2
- NMBR | c.1005C>T p.F335= | Silent (SNP) | VAF 8/138 reads (6%) | catalogued as rs1165624521, COSV104382252, COSV57801106; called by muse, mutect2
- PILRA | c.435C>T p.T145= | Silent (SNP) | VAF 20/72 reads (28%) | catalogued as COSV52200147; called by muse, mutect2, varscan2
- SP6 | c.735C>T p.P245= | Silent (SNP) | VAF 28/73 reads (38%) | catalogued as COSV100647080, COSV60617400; called by muse, mutect2, varscan2
